Somatic mutation profile of tumor specimen TCGA-AG-A00Y-01A (aliquot TCGA-AG-A00Y-01A-02W-A00K-09) from TCGA case TCGA-AG-A00Y, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-AG-A00Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce11fdf2-cd99-48fb-8764-5321bc434877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A00Y-10A (Blood Derived Normal), aliquot TCGA-AG-A00Y-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a985359-1282-47a2-ad33-c64610fc7ef6

The open-access MAF lists 252 somatic variants for this specimen: 185 protein-altering or splice-affecting, 61 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 61, Nonsense Mutation 12, Frame Shift Del 8, Splice Site 4, Intron 3, RNA 3, In Frame Del 2, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 64/91 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs201908745; called by muse, mutect2, varscan2
- AC134980.2 | c.934T>G p.F312V | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60908859; called by mutect2, varscan2
- ACSS3 | c.2000C>A p.T667N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99699132; called by muse, mutect2, varscan2
- ADGRB3 | c.4028A>G p.Y1343C | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1220188917, COSV99485988; called by muse, mutect2, varscan2
- AHNAK2 | c.7120G>T p.D2374Y | Missense Mutation (SNP) | VAF 1530/5581 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1176431474, COSV100318178; called by muse, mutect2, varscan2
- ALMS1 | c.7297C>T p.P2433S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs938039488, COSV52518997; called by muse, mutect2, varscan2
- AMIGO2 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs372100851, COSV99873701; called by muse, mutect2, varscan2
- ANKIB1 | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV56065103; called by muse, mutect2, varscan2
- ANOS1 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99391071; called by muse, mutect2, varscan2
- ARHGAP21 | c.4289C>T p.P1430L | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as COSV100256407; called by muse, mutect2, varscan2
- ATAD5 | c.3449G>A p.G1150E | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430063; called by muse, mutect2
- ATCAY | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV100008879; called by muse, mutect2, varscan2
- ATG4A | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 338/416 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV58966093; called by muse, mutect2, varscan2
- ATL1 | c.990G>A p.K330= | Splice Region (SNP) | VAF 78/287 reads (27%) | catalogued as COSV63297890; called by muse, mutect2, varscan2
- ATP8A2 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 57/449 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV54970979; called by muse, mutect2, varscan2
- ATP8B4 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99466007, COSV99466434; called by muse, mutect2, varscan2
- AXDND1 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV100858518; called by muse, varscan2
- BBS9 | c.2317G>A p.D773N (on ENST00000242067 / NM_001348036.1; = p.D733N on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 669/781 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99629054; called by muse, mutect2, varscan2
- C20orf85 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs547087983, COSV64519286; called by muse, mutect2, varscan2
- C9orf43 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 573/660 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928469; called by muse, mutect2, varscan2
- CA8 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs200882621, COSV100527068; called by muse, mutect2, varscan2
- CAPN9 | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99680721; called by muse, mutect2
- CARMIL1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs939168766, COSV61522505; called by muse, mutect2, varscan2
- CATSPERB | c.1058T>C p.I353T | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99831474; called by muse, mutect2, varscan2
- CC2D2B | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV60358959; called by muse, mutect2, varscan2
- CD109 | c.2492C>A p.P831H | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV99754013; called by muse, mutect2, varscan2
- CDH17 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 36/526 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV50331343; called by muse, mutect2
- CEMIP2 | c.2930G>C p.S977T | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100987131; called by muse, mutect2, varscan2
- CEP41 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as COSV99782793; called by muse, mutect2, varscan2
- CHDH | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100179770, COSV59456233; called by mutect2, varscan2
- COL11A2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1562391013, COSV100553826, COSV59498239; called by muse, mutect2, varscan2
- COX15 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); catalogued as COSV50013402; called by muse, mutect2
- CRBN | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV104372047, COSV99214231; called by muse, mutect2, varscan2
- CRBN | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs760055652, COSV99214233; called by muse, varscan2
- CRYBG3 | c.6818C>T p.P2273L | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV51715166; called by muse, mutect2
- CTSC | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 8/233 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99910796; called by muse, mutect2
- CUL4A | c.1366G>A p.D456N (on ENST00000375440 / NM_001008895.4; = p.D356N on NM_003589.3) | Missense Mutation (SNP) | VAF 323/495 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100417393; called by muse, mutect2, varscan2
- CYP19A1 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99547858; called by muse, mutect2, varscan2
- CYP26A1 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV56417771, COSV56419646; called by muse, mutect2, varscan2
- DCAF12L2 | c.880A>C p.T294P | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100758689; called by muse, mutect2, varscan2
- DDX18 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 40/311 reads (13%) | catalogued as COSV99604639; called by muse, varscan2
- DENND5B | c.3695C>T p.T1232I | Missense Mutation (SNP) | VAF 107/142 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV60901941, COSV60906942; called by muse, mutect2, varscan2
- DGKH | c.3512T>C p.I1171T | Missense Mutation (SNP) | VAF 100/486 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV99819154; called by muse, mutect2, varscan2
- DKKL1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs369639830, COSV55561344; called by muse, mutect2, varscan2
- DNMT3B | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 115/397 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52422016, COSV99142467; called by muse, mutect2, varscan2
- EFCAB6 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99413814; called by muse, mutect2, varscan2
- EMB | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as rs866302109, COSV57482353; called by muse, mutect2, varscan2
- ERBB2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 146/162 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV54068645, COSV99508444; called by muse, mutect2, varscan2
- FAAP24 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99578956; called by muse, mutect2, varscan2
- FAM126A | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101300016; called by muse, mutect2
- FAT4 | c.3413C>G p.S1138C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV101272516, COSV67893400; called by muse, mutect2, varscan2
- FBXO30 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 198/401 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99395283; called by muse, mutect2, varscan2
- FCRL5 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 134/311 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as rs376321602, COSV62516000, COSV62519878; called by muse, mutect2, varscan2
- FOXP2 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV100647049, COSV63493794; called by muse, mutect2, varscan2
- FOXP2 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100647053; called by muse, mutect2, varscan2
- FRMPD2 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 219/293 reads (75%) | catalogued as COSV100563970; called by muse, mutect2, varscan2
- GABRG2 | c.1324G>A p.E442K (on ENST00000361925 / NM_001375343.1; = p.E402K on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV62717693; called by muse, mutect2, varscan2
- GAL3ST4 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs760276260, COSV99444856; called by muse, mutect2, varscan2
- GALNT11 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100231921; called by muse, mutect2
- GAN | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.749); catalogued as COSV101634014; called by muse, mutect2, varscan2
- GLYCTK | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV99980849; called by muse, mutect2, varscan2
- GON4L | c.1231C>G p.Q411E | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as COSV55201007; called by mutect2, varscan2
- GPD2 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100133416; called by muse, mutect2, varscan2
- HECW2 | c.4525G>T p.E1509* | Nonsense Mutation (SNP) | VAF 168/639 reads (26%) | catalogued as COSV99647819; called by muse, mutect2, varscan2
- IGSF11 | c.181G>A p.V61I (on ENST00000393775 / NM_001015887.3; = p.V60I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100677486, COSV61176766; called by muse, mutect2, varscan2
- IL1R2 | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100208129; called by muse, mutect2, varscan2
- ISL1 | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV100045561; called by muse, mutect2, varscan2
- JMJD1C | c.3383C>T p.A1128V | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs745461131, COSV100550688; called by muse, mutect2, varscan2
- KCNS1 | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV60260421; called by muse, mutect2
- KCTD20 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.368); catalogued as COSV99536091; called by muse, mutect2, varscan2
- KDM5A | c.3781C>T p.R1261W | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773466573, COSV66995556; called by muse, mutect2, varscan2
- KDM5C | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948873; called by muse, mutect2
- KEL | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as rs1204570432, COSV100787170; called by muse, mutect2, varscan2
- KHDC3L | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV64863026, COSV64863081; called by muse, mutect2, varscan2
- KIAA0100 | c.6503G>A p.S2168N | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99972193; called by muse, mutect2
- KIFAP3 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.626); catalogued as COSV100847011; called by muse, mutect2, varscan2
- KLF5 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 597/917 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV100890568; called by muse, mutect2, varscan2
- KLHL23 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55867986; called by muse, mutect2, varscan2
- KLK3 | c.494-1G>A p.X165_splice | Splice Site (SNP) | VAF 18/178 reads (10%) | catalogued as COSV100386037; called by muse, mutect2
- LMTK3 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99540778; called by muse, mutect2
- LPGAT1 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 228/444 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100878164; called by muse, mutect2, varscan2
- LRRC8C | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV64995833; called by muse, mutect2, varscan2
- LYST | c.4871A>C p.D1624A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV101089855; called by muse, mutect2, varscan2
- MAP2K4 | c.814-1G>T p.X272_splice | Splice Site (SNP) | VAF 35/71 reads (49%) | catalogued as COSV62256340, COSV62261009; called by muse, mutect2, varscan2
- MTMR1 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64892196; called by muse, varscan2
- MUC17 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1562806956, COSV100074118; called by muse, mutect2
- MUC6 | c.3620C>T p.T1207M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs577998306, COSV70148232; called by muse, mutect2
- MUSK | c.2572C>T p.R858C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200450921, COSV51887466; called by muse, mutect2, varscan2
- MYO16 | c.1497G>T p.R499S | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99193891; called by muse, mutect2
- MYO19 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 258/294 reads (88%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as rs1409270197; called by muse, mutect2, varscan2
- NAE1 | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV99323209; called by muse, mutect2, varscan2
- NAXE | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV100963970; called by muse, mutect2, varscan2
- NDST3 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs778628771, COSV56626922; called by muse, mutect2, varscan2
- NF1 | c.5645G>A p.C1882Y (on ENST00000358273 / NM_001042492.3; = p.C1861Y on NM_000267.3) | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.127); catalogued as COSV62195751, COSV62225413; called by muse, mutect2
- NFU1 | c.163C>T p.P55S (on ENST00000410022 / NM_001002755.4; = p.P31S on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100361238; called by muse, mutect2, varscan2
- NLGN4Y | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.274); catalogued as COSV52970980; called by muse, mutect2, varscan2
- NOTCH2 | c.6418C>T p.Q2140* | Nonsense Mutation (SNP) | VAF 41/258 reads (16%) | catalogued as CM112316, COSV56680791; called by muse, mutect2, varscan2
- NPR1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs753081607, COSV64117677; called by muse, mutect2, varscan2
- NRCAM | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100694978; called by muse, mutect2, varscan2
- NUFIP1 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 842/1330 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100998026; called by muse, mutect2, varscan2
- OR10H5 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100454754; called by muse, mutect2
- OR51S1 | c.713G>T p.R238I | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV59057387; called by muse, mutect2, varscan2
- OR5D16 | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 70/539 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV101003838, COSV65723143; called by muse, mutect2, varscan2
- PAICS | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | PolyPhen possibly damaging (0.612); catalogued as COSV51709778; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1024A>C p.K342Q (on ENST00000259318 / NM_001136562.3; = p.K573Q on NM_007203.5) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV52180358; called by mutect2, varscan2
- PALMD | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 128/186 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1487947192, COSV54163607; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2
- PCDH11Y | c.1580G>T p.S527I (on ENST00000400457 / NM_032973.2; = p.S516I on NM_032971.3) | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1569475042, COSV99290245; called by muse, mutect2, varscan2
- PDCL | c.173-1G>A p.X58_splice | Splice Site (SNP) | VAF 265/374 reads (71%) | catalogued as COSV99414161; called by muse, mutect2, varscan2
- PDP1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 191/292 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52601452, COSV99892638; called by muse, mutect2, varscan2
- PDZRN4 | c.2688C>G p.D896E (on ENST00000402685 / NM_001164595.2; = p.D638E on NM_013377.4) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114969, COSV54193409; called by muse, mutect2
- PHAX | c.554T>A p.M185K | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99881569; called by muse, mutect2
- PIWIL3 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 101/881 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.115); catalogued as COSV100177798; called by muse, mutect2, varscan2
- PLAG1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as rs144724863; called by muse, mutect2, varscan2
- PLD5 | c.1036G>A p.D346N (on ENST00000442594; = p.D284N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as rs201629512, COSV100141391; called by muse, mutect2, varscan2
- PLEKHG1 | c.2516G>A p.W839* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV100651746; called by muse, mutect2, varscan2
- POTEA | c.1249C>T p.L417F (on ENST00000519951 / NM_001005365.2; = p.L371F on NM_001002920.1) | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); catalogued as rs775996586; called by muse, mutect2, varscan2
- PPP1R12B | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as rs763306615, COSV100407891; called by muse, mutect2, varscan2
- PPP2R3A | c.2795C>T p.S932L | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53868179, COSV99387639; called by muse, mutect2, varscan2
- PRKD1 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV100119016; called by muse, mutect2
- PRKN | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100630103; called by muse, mutect2, varscan2
- PRPF3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100254910; called by muse, mutect2
- RAB6C | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.253); catalogued as COSV101308530; called by mutect2, varscan2
- RECK | c.2833G>A p.V945I | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100937545; called by muse, mutect2
- RELN | c.3912+1G>A p.X1304_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | catalogued as COSV100634171; called by muse, mutect2, varscan2
- RIMS2 | c.1010C>T p.P337L (on ENST00000666250 / NM_001348490.2; = p.P145L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51713227, COSV99160783; called by muse, mutect2, varscan2
- RNASEL | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV100842617; called by muse, mutect2
- ROBO1 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV71397554; called by muse, mutect2, varscan2
- RSF1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426761612, COSV100407466; called by muse, mutect2
- RTL3 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100329923; called by muse, mutect2, varscan2
- S1PR1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs769569528, COSV59514504; called by muse, mutect2, varscan2
- SACM1L | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV101203777; called by muse, mutect2
- SAV1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 148/222 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100220822; called by muse, mutect2, varscan2
- SCFD2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 636/833 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV101189425; called by muse, mutect2, varscan2
- SLC12A3 | c.967_968del p.D323Hfs*9 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV52638019; called by mutect2, varscan2
- SLCO1C1 | c.1259G>C p.S420T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56871110, COSV99859449; called by muse, mutect2
- SLFN11 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV100390785; called by muse, mutect2, varscan2
- SLITRK3 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV99579580; called by muse, mutect2, varscan2
- SMARCD2 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV56742389; called by muse, mutect2, varscan2
- SP110 | c.1819C>G p.R607G | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV51269334; called by muse, mutect2, varscan2
- SULF1 | c.2552G>A p.G851E | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs868388161, COSV52674483; called by muse, mutect2
- SYNE1 | c.10918C>T p.Q3640* | Nonsense Mutation (SNP) | VAF 401/530 reads (76%) | catalogued as COSV99570912; called by muse, mutect2, varscan2
- TCERG1L | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100894363; called by muse, mutect2, varscan2
- TEX13A | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV100781579; called by muse, mutect2, varscan2
- TPD52L1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs375008815; called by muse, mutect2, varscan2
- TRANK1 | c.6559A>G p.I2187V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.474); catalogued as COSV57161222; called by muse, mutect2
- TRIM43 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 398/560 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV55529124; called by muse, mutect2, varscan2
- TRIM46 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.657); catalogued as COSV99826013; called by muse, mutect2, varscan2
- TRIM69 | c.1072C>T p.P358S (on ENST00000329464 / NM_182985.5; = p.P199S on NM_080745.5) | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs372919928; called by muse, mutect2
- TRMT10C | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59306639; called by muse, mutect2, varscan2
- TRO | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201094980, COSV51499655; called by muse, mutect2, varscan2
- TSHR | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV99992256; called by muse, mutect2, varscan2
- TTN | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | PolyPhen probably damaging (0.997); catalogued as rs764892312, COSV100588460, COSV60218568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UPF3B | c.893G>A p.R298K (on ENST00000276201 / NM_080632.3; = p.R285K on NM_023010.3) | Missense Mutation (SNP) | VAF 426/603 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99352260; called by muse, mutect2, varscan2
- VTN | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 90/101 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782023049, COSV56872558; called by muse, mutect2, varscan2
- WAPL | c.2797_2803del p.I933Gfs*6 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as COSV53939083; called by mutect2, pindel, varscan2
- ZBED9 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as COSV101509318; called by muse, mutect2
- ZBTB24 | c.1685A>C p.N562T | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100018547; called by muse, mutect2, varscan2
- ZDBF2 | c.4144C>T p.Q1382* | Nonsense Mutation (SNP) | VAF 121/219 reads (55%) | catalogued as COSV100984689, COSV65629087; called by muse, mutect2, varscan2
- ZFHX4 | c.7927G>A p.G2643R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375729228, COSV50531518; called by muse, mutect2, varscan2
- ZFYVE1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs142709121; called by muse, mutect2, varscan2
- ZNF429 | c.1586A>C p.K529T | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.874); catalogued as COSV100642096, COSV61918308; called by muse, mutect2, varscan2
- ZNF556 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100298810; called by muse, mutect2, varscan2
- ZNF585B | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV57216646; called by muse, mutect2
- ZNF606 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV58705475; called by muse, mutect2
- ZNF786 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100302910; called by muse, mutect2, varscan2
- APC | c.340_347del p.P114Ffs*22 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- ARRDC3 | c.980A>G p.Q327R | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2
- DDB1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- DNAH11 | c.9085del p.E3029Kfs*24 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- FLG | c.7584_7634del p.G2531_S2547del | In Frame Del (DEL) | VAF 23/154 reads (15%) | called by pindel, varscan2*
- GFOD2 | c.630_657del p.I211Mfs*18 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2*, pindel
- IGKV1-9 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 437/707 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- KANK1 | c.2359del p.T787Lfs*4 | Frame Shift Del (DEL) | VAF 568/918 reads (62%) | called by mutect2, pindel
- LATS1 | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- LRP5 | c.3787del p.Q1263Sfs*176 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- MAP3K15 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.448); called by muse, mutect2
- MBOAT1 | c.108del p.F36Lfs*57 | Frame Shift Del (DEL) | VAF 323/493 reads (66%) | called by mutect2, pindel, varscan2
- MORC4 | c.1386-2_1392dup p.R462_C464dup | In Frame Ins (INS) | VAF 28/63 reads (44%) | called by mutect2, varscan2
- NUP155 | c.3592C>T p.L1198F (on ENST00000231498 / NM_153485.3; = p.L1139F on NM_004298.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5 | c.2018G>A p.G673D | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- TNS1 | c.4378_4380del p.S1460del | In Frame Del (DEL) | VAF 39/69 reads (57%) | called by mutect2, pindel, varscan2
- TRAV22 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 157/236 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ACACA | c.6660C>T p.A2220= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs548821816; called by muse, mutect2, varscan2
- ADAMTS20 | c.45G>A p.S15= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV67135531; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2982G>A p.K994= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs1380226483, COSV99719862; called by muse, mutect2
- ANAPC7 | c.1797G>A p.Q599= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV101482870; called by muse, mutect2, varscan2
- BPTF | c.4866C>T p.N1622= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as rs148696633; called by muse, mutect2, varscan2
- C19orf54 | c.663C>T p.F221= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99648920; called by muse, mutect2, varscan2
- CDC42BPA | c.3291G>A p.V1097= (on ENST00000334218 / NM_001366019.2; = p.V1084= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/268 reads (47%) | catalogued as COSV100506006; called by muse, mutect2, varscan2
- CILP | c.672C>T p.F224= | Silent (SNP) | VAF 82/122 reads (67%) | catalogued as COSV56025265; called by muse, varscan2
- DENND2D | c.1305C>T p.I435= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100718732; called by muse, mutect2, varscan2
- DIAPH2 | c.2776C>T p.L926= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100233763; called by muse, mutect2
- DNAH11 | c.10419G>T p.L3473= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1460402546, COSV60975442; called by muse, mutect2, varscan2
- DOT1L | c.606C>T p.F202= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs1350553431, COSV101288722; called by muse, mutect2, varscan2
- DPP4 | c.1540C>T p.L514= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV100858942; called by muse, mutect2, varscan2
- DRP2 | c.2031C>T p.F677= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs190486006, COSV100871966; called by muse, mutect2, varscan2
- EIF4A3 | c.720G>A p.L240= | Silent (SNP) | VAF 251/329 reads (76%) | catalogued as COSV53920586; called by muse, mutect2, varscan2
- ELAPOR2 | c.1851G>A p.S617= (on ENST00000450689 / NM_001142749.3; = p.S450= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs369087183; called by muse, mutect2, varscan2
- EPB41L3 | c.2103G>A p.G701= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV59468270; called by muse, mutect2, varscan2
- FEM1A | c.1560G>A p.Q520= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1378987556, COSV54164679; called by muse, mutect2, varscan2
- FRY | c.4716C>T p.L1572= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as rs1223238121, COSV66567765; called by muse, varscan2
- GJA8 | c.519C>T p.Y173= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as rs782648768, COSV53787636; called by muse, mutect2, varscan2
- KALRN | c.297C>T p.D99= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV99565648; called by muse, mutect2
- KIF21A | c.1980G>A p.L660= (on ENST00000361418 / NM_001378440.1; = p.L647= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100735531; called by muse, mutect2
- KIT | c.2442C>T p.A814= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV99854782; called by muse, mutect2
- LAMB4 | c.2028C>T p.I676= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs1213190636, COSV99224768; called by muse, mutect2, varscan2
- LARP6 | c.1368G>A p.R456= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100150928; called by muse, mutect2, varscan2
- MAP4 | c.1101C>T p.S367= | Silent (SNP) | VAF 130/2632 reads (5%) | catalogued as COSV100806002; called by muse, mutect2
- MDN1 | c.9732G>A p.A3244= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1269483617, COSV65517379; called by muse, mutect2, varscan2
- MLYCD | c.636C>T p.I212= | Silent (SNP) | VAF 486/581 reads (84%) | catalogued as COSV99299357; called by muse, mutect2, varscan2
- MS4A10 | c.324G>A p.L108= | Silent (SNP) | VAF 421/611 reads (69%) | catalogued as COSV100382361; called by muse, mutect2, varscan2
- NAT1 | c.765C>T p.F255= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- NLGN4X | c.2166T>C p.A722= | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as rs1173303957, COSV99322744; called by muse, mutect2, varscan2
- OR2F2 | c.813G>A p.E271= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV101283829; called by muse, mutect2, varscan2
- OR51E1 | c.15C>A p.P5= | Silent (SNP) | VAF 190/510 reads (37%) | catalogued as COSV67810758; called by muse, mutect2, varscan2
- PDIA3 | c.576G>T p.L192= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as COSV100295174; called by muse, varscan2
- PRSS55 | c.336C>T p.S112= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs750765458, COSV60807909; called by muse, mutect2, varscan2
- REV3L | c.8745A>T p.G2915= | Silent (SNP) | VAF 73/382 reads (19%) | catalogued as COSV100725382; called by muse, mutect2, varscan2
- RNLS | c.984C>T p.I328= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs977191957, COSV100076732; called by muse, mutect2, varscan2
- RRN3 | c.438G>A p.P146= | Silent (SNP) | VAF 81/213 reads (38%) | catalogued as rs369978373; called by muse, mutect2, varscan2
- SCN2A | c.2802C>A p.I934= | Silent (SNP) | VAF 152/429 reads (35%) | catalogued as COSV51836585, COSV51852352; called by muse, mutect2, varscan2
- SEC16B | c.2016C>T p.L672= | Silent (SNP) | VAF 271/416 reads (65%) | catalogued as COSV57629140; called by muse, mutect2, varscan2
- SLC52A3 | c.780C>T p.V260= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV99448156; called by muse, varscan2
- SMG8 | c.2889G>A p.E963= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV56285237, COSV99958931; called by muse, mutect2
- SNX17 | c.213G>A p.E71= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99277728; called by muse, varscan2
- SPHKAP | c.4566G>A p.Q1522= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as COSV60890878; called by muse, mutect2
- ST18 | c.798C>T p.P266= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99390256; called by muse, mutect2, varscan2
- STEAP1 | c.366C>A p.S122= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV51882560; called by muse, mutect2
- TAF6 | c.516G>A p.Q172= | Silent (SNP) | VAF 1139/1249 reads (91%) | catalogued as COSV100693460; called by muse, mutect2, varscan2
- TF | c.1845C>T p.C615= | Silent (SNP) | VAF 73/407 reads (18%) | catalogued as rs142894328; called by muse, mutect2, varscan2
- TLR7 | c.1374G>A p.Q458= | Silent (SNP) | VAF 19/192 reads (10%) | catalogued as COSV101027964; called by muse, mutect2
- TMCO4 | c.1296G>A p.L432= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99617023; called by muse, mutect2
- TMEM132D | c.1932T>C p.S644= | Silent (SNP) | VAF 110/167 reads (66%) | catalogued as COSV101242954; called by muse, mutect2, varscan2
- TRPM3 | c.2694G>A p.K898= (on ENST00000357533 / NM_001366142.2; = p.K741= on NM_020952.6) | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as COSV62592809; called by muse, mutect2, varscan2
- TTN | c.49404G>A p.R16468= (on ENST00000591111; = p.R9044= on NM_003319.4) | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV60271948; called by muse, mutect2, varscan2
- TUBD1 | c.432G>A p.G144= | Silent (SNP) | VAF 34/396 reads (9%) | catalogued as rs748857715, COSV100360175; called by muse, mutect2
- U2AF1L4 | c.327C>T p.L109= (on ENST00000412391; = p.L70= on NM_144987.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 118/142 reads (83%) | catalogued as COSV53074395, COSV99495489; called by muse, mutect2, varscan2
- ZBED8 | c.438C>T p.I146= | Silent (SNP) | VAF 81/205 reads (40%) | catalogued as COSV101283533; called by muse, mutect2, varscan2
- ZCCHC12 | c.90G>A p.G30= | Silent (SNP) | VAF 1654/1728 reads (96%) | catalogued as COSV100038429, COSV100038592; called by mutect2, varscan2
- ZNF181 | c.873A>G p.K291= | Silent (SNP) | VAF 22/598 reads (4%) | catalogued as COSV67626296; called by muse, mutect2
- ZNF417 | c.1473G>T p.P491= | Silent (SNP) | VAF 96/336 reads (29%) | catalogued as rs201800509, COSV56309663, COSV56310343; called by muse, varscan2
- ZNF614 | c.99C>T p.Y33= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV99571848; called by muse, mutect2
- ZP3 | c.969C>T p.N323= (on ENST00000394857 / NM_001110354.2; = p.N272= on NM_007155.6) | Silent (SNP) | VAF 1084/1288 reads (84%) | catalogued as COSV60635043; called by muse, mutect2, varscan2
- CHD6 | c.-23-12694C>T | Intron (SNP) | VAF 10/51 reads (20%) | catalogued as rs780152773, COSV58562840; called by muse, mutect2, varscan2
- ISCA1P1 | n.126G>A | RNA (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- LIMK2 | c.1773-1420G>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99314120; called by muse, mutect2
- NEK7 | c.198+3281C>T | Intron (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100954441; called by muse, varscan2
- NXF5 | n.1531G>A | RNA (SNP) | VAF 107/130 reads (82%) | catalogued as rs373035757, COSV53793865; called by muse, mutect2, varscan2
- SNORD114-15 | n.9T>C | RNA (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
